Somatic mutation profile of tumor specimen 0DLIFL from CCDI case PBBYAT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Clear cell meningioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.8 years (7,216 days).
Specimen 0DLIFL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 784b284e-640f-48ad-92f6-3966699b3911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIF5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c3e8d73-f5ec-4dab-a375-beea9ee0a4aa

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP5F1B | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 44/796 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100008095, COSV56261268; called by muse, mutect2
- NEK1 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 57/1006 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs540032875; called by muse, mutect2
- DOT1L | c.3215G>C p.R1072P | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPK8IP3 | c.11T>G p.I4S | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- ARHGAP22 | c.42C>T p.S14= | Silent (SNP) | VAF 42/658 reads (6%) | catalogued as rs1023053815; called by muse, mutect2
- PLCXD2 | c.549C>T p.A183= | Silent (SNP) | VAF 160/735 reads (22%) | called by muse, mutect2, varscan2
- TENM4 | c.2805C>G p.P935= | Silent (SNP) | VAF 62/672 reads (9%) | called by muse, mutect2
- ZNF628 | c.1146C>T p.G382= | Silent (SNP) | VAF 43/142 reads (30%) | called by muse, mutect2, varscan2
- FANCL | c.775+40T>C | Intron (SNP) | VAF 49/170 reads (29%) | called by muse, mutect2, varscan2
